MMRF case MMRF_1656 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/415c02bc-e6de-4eb7-9b5c-157cfb6aef0e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 523 days (1.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.0 years (25,923 days); ISS stage: III; Days to last known disease status: 523 days (1.4 years); Days to last follow up: 523 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 79 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 79 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 110 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 133 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 229 days; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 444 days (1.2 years); Days to treatment end: 505 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 512 days (1.4 years); Days to treatment end: 515 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 523.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 3.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 502 mg/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 41.4 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 9.24 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.92 ×10⁹/L; Platelets 388 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.53 mmol/L; Albumin 28 g/L; Total Protein 9.4 g/dL; Glucose 6.71 mmol/L; C-Reactive Protein 1.13 mg/dL.
- Day 64 (ECOG 1): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 114 mg/dL; Immunoglobulin G 5.68 g/L; Immunoglobulin A 9.3 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.96 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 402 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 161 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.1 mg/dL; Immunoglobulin G 8.63 g/L; Immunoglobulin A 6.23 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.62 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 5.67 mmol/L.
- Day 257 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 30.4 mg/dL; Immunoglobulin G 6.99 g/L; Immunoglobulin A 4.5 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 3.55 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.
- Day 302: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.5 mg/dL; Immunoglobulin G 6.07 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.53 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 0.58 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 6.49 mmol/L.
- Day 433: M Protein 3.1 g/dL; Immunoglobulin G 3.99 g/L; Immunoglobulin A 29.6 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 9.28 µg/mL; Hemoglobin 4.84 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.97 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 39.2 g/L; Total Protein 9.2 g/dL; Glucose 4.02 mmol/L.
- Day 505 (ECOG 1): M Protein 3.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 949 mg/dL; Immunoglobulin G 3.2 g/L; Immunoglobulin A 36.3 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 9.56 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 1 ×10⁹/L; Absolute Neutrophil 0.47 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.6 mmol/L; Albumin 30 g/L; Total Protein 8.6 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -17: Weight: 70 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1656_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1656_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
- Sample MMRF_1656_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 505 days (1.4 years).
